Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JD-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site: Buccal mucosa
CO6.0
9/29/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Buccal mucosa

1 - "Neck lymph nodes - Right":

- Eighteen lymph nodes with no evidence of metastatic carcinoma (0/18).
- Salivary gland fragments with congestion, uninvolved by neoplasia

2 - "Neck lymph nodes":

- Two of seven lymph nodes involved by metastatic carcinoma (2/7), with capsular involvement.

3 - Anterior margin uninvolved by neoplasia

4 - "Retromolar lesion surgical excision specimen":

- Poorly differentiated squamous cell carcinoma, ulcerated, measured 4.1 cm, 1.4 cm deep, with necrosis sites.
- Lymphovascular invasion: present.
- Perineural invasion: present.
- Osseous tissue involved by carcinoma.
- Intense peritumoral desmoplasia.
- Scarce peritumoral lymphocitary infiltrate.
- Deep margin involved by carcinoma.
- Other surgical margins uninvolved by carcinoma.

Diagnostic Discrepancy	8/12/13	✓
NIPTAA Discrepancy		✓

Source: NCI Genomic Data Commons file ba1ee1a5-425d-4449-86fd-3283dce0cd6e (TCGA-UF-A7JD.8B218C4E-A9AB-486A-9A8E-B3001C98F86A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).